Gene-level copy-number profile of tumor specimen HTMCP-01-01-00012-01A from CGCI case HTMCP-01-01-00012, project CGCI-HTMCP-DLBCL (HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Primary diffuse large B-cell lymphoma of the CNS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 39.6 years (14,469 days).
Specimen HTMCP-01-01-00012-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 182e7ae8-2c95-41a3-820a-f5e1daf8d223.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-01-01-00012-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,777 have no estimate.
https://portal.gdc.cancer.gov/files/37bfe66d-1ae2-415a-9168-ee2847942822

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 110; copy number 1: 2,993; copy number 2: 54,934; copy number 3: 561; copy number 4: 164; copy number 5: 50; copy number 6: 7; copy number 8: 1; copy number 10: 1; copy number 11: 8; copy number 12: 4; copy number 13: 8; copy number 18: 1; copy number 19: 2; copy number 31: 2.

Homozygous deletions (total copy number 0; autosomes only): 110 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,857,161–89,245,596, 35 genes (within-gene range 0–2): IGKC, IGKJ5, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr14:105,851,705–106,211,453, 75 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 84 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:120,913,184–121,009,291, 4 genes, copy number 6 (within-gene range 4–6): LINC00623, RNVU1-4, AC241377.4, U1.
- chr1:143,955,364–144,373,659, 10 genes, copy number 5–11: FAM72C, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E.
- chr1:145,095,974–145,112,696, 1 gene, copy number 18: FAM72D.
- chr1:148,482,548–149,556,361, 25 genes, copy number 5–13: PPIAL4G, RNVU1-27, NBPF14, NOTCH2NLB, RNU6-1171P, NUDT4B, SEC22B3P, AC245389.1, PDE4DIP, RN7SKP88, RNU2-38P, AC239802.1, AC239802.2, AC239804.1, NBPF9, AC239804.2, RNVU1-24, AC245297.3, AC245297.1, AC245297.2, 7SK, SEC22B2P, NOTCH2NLC, AC242842.3, NBPF19.
- chr1:149,782,671–149,812,373, 3 genes, copy number 5: FCGR1A, H2BC18, AC243772.2.
- chr5:69,985,204–70,078,522, 4 genes, copy number 5–10: CDH12P2, SERF1B, SMN2, AC140134.1.
- chr5:70,197,255–70,918,530, 10 genes, copy number 5–12: AC138866.1, GUSBP14, GTF2H2B, AC146944.2, NAIPP1, AC146944.1, GUSBP15, GUSBP16, AC139272.1, SERF1A.
- chr5:70,968,166–71,025,339, 1 gene, copy number 5: NAIP.
- chr5:71,197,646–71,259,238, 2 genes, copy number 31: GUSBP9, GUSBP17.
- chr7:76,968,197–77,004,308, 3 genes, copy number 5 (within-gene range 2–5): FDPSP7, AC114737.1, DTX2P1.
- chr9:41,310,816–41,764,175, 15 genes, copy number 5: AL354718.2, CDRT15P6, AL354718.1, AL591926.3, SNORA70, RN7SL565P, AL591926.7, AL591926.6, AL591926.5, AL591926.2, FAM242F, Y_RNA, AL591926.1, AL591926.4, AL162731.1.
- chr15:32,313,126–32,315,654, 1 gene, copy number 5: AC139426.1.
- chr15:32,398,956–32,435,233, 3 genes, copy number 6 (within-gene range 4–6): AC135983.1, ULK4P1, U8.
- chr16:18,357,026–18,379,331, 2 genes, copy number 19 (within-gene range 7–19): AC126755.4, NPIPA9.

Autosomal genes at a single copy (total copy number 1): 146. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
